FM case AD12919 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/ed64d6fe-2ddf-464a-9fac-04470426dfc7

Female, 62.9 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
